Somatic mutation profile of tumor specimen 0DVM1M from CCDI case PBCMNY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 16.7 years (6,103 days).
Specimen 0DVM1M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c95fd88-cafc-4cc2-a6d1-a492c39163fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbbc06fd-c11e-4c9d-bbc4-3d98280c25f7

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 1, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV56997650; called by muse, mutect2, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 14/469 reads (3%) | catalogued as COSV59989381; called by muse, mutect2
- CHRFAM7A | c.-31-1G>A | Splice Site (SNP) | VAF 47/404 reads (12%) | catalogued as rs781651933; called by muse, varscan2
- CNST | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs369555056; called by muse, mutect2
- CNTNAP2 | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 34/757 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs139234992; ClinVar: uncertain significance; called by muse, mutect2
- DERA | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 24/722 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188925376; called by muse, mutect2
- GLI3 | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227441848; called by muse, mutect2
- RELB | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs551709862; called by muse, mutect2
- TLR5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs187499609, COSV60561128; called by muse, mutect2
- ALPG | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CRMP1 | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 29/470 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2
- DGAT2L6 | c.78A>G p.I26M | Missense Mutation (SNP) | VAF 60/637 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- FAT3 | c.11343G>T p.R3781S | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GOLM2 | c.979_985del p.G327Tfs*13 | Frame Shift Del (DEL) | VAF 50/497 reads (10%) | called by mutect2, varscan2
- NUF2 | c.655A>G p.K219E | Missense Mutation (SNP) | VAF 109/769 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PI4KA | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ABCB4 | c.1746G>T p.R582= | Silent (SNP) | VAF 27/384 reads (7%) | called by muse, mutect2
- COL11A2 | c.2178C>T p.D726= (on ENST00000341947 / NM_080680.3; = p.D619= on NM_080679.2) | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as rs138650682; ClinVar: likely benign; called by muse, mutect2
- PAPLN | c.306G>C p.R102= | Silent (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- DDX20 | c.824-45C>T | Intron (SNP) | VAF 15/260 reads (6%) | called by muse, mutect2
- PDE8B | c.-21G>A | 5'UTR (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
